Somatic mutation profile of tumor specimen 0DY8KQ from CCDI case PBCSDJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 0.2 years (73 days).
Specimen 0DY8KQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec34934c-d430-42dc-850a-a6a6f9415875.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY8KG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa0cbdfb-458e-4676-bb98-153f424e6054

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH17 | c.11642C>T p.P3881L | Missense Mutation (SNP) | VAF 202/1158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780967834, COSV67753411; called by muse, mutect2, varscan2
- FBN2 | c.2647C>A p.L883I | Missense Mutation (SNP) | VAF 57/1483 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- HMGCS2 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 17/559 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.396); called by muse, mutect2
- F7 | c.*62T>C | 3'UTR (SNP) | VAF 44/182 reads (24%) | called by mutect2, varscan2
